Somatic mutation profile of tumor specimen BA2093D (aliquot aq-BA2093D) from BEATAML1.0 case 2343, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.4 years (18,778 days).
Specimen BA2093D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5a29872-e36e-4b66-b088-5fd2c77d0f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2310D (Solid Tissue Normal), aliquot aq-BA2310D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03503887-aef2-46e4-abf8-409dbef59bbf

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Splice Site 3, Silent 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 125/282 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-2A>C p.X187_splice | Splice Site (SNP) | VAF 149/376 reads (40%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 31/97 reads (32%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AKNAD1 | c.2456C>T p.T819M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs966666421; called by muse, mutect2, varscan2
- AMER3 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs773805721; called by muse, varscan2
- CELSR1 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs756362507; called by muse, mutect2, varscan2
- DOCK3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200070432, COSV56532249; called by muse, mutect2, varscan2
- DSP | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1554107626, COSV101131882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITFG2 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs770430549; called by muse, mutect2, varscan2
- MAMLD1 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 104/119 reads (87%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV53372552; called by muse, mutect2, varscan2
- SPEG | c.7655C>T p.P2552L | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs373771648; called by muse, mutect2, varscan2
- FAM53B | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- HECTD1 | c.2846C>A p.A949D | Missense Mutation (SNP) | VAF 160/287 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIAA0825 | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2
- LTBP4 | c.791C>A p.A264E (on ENST00000308370 / NM_001042544.1; = p.A227E on NM_003573.2) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2
- MYH14 | c.2369G>A p.G790E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPEN | c.8246C>A p.A2749E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2
- SUPT16H | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBC1D24 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2
- ZNF724 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- ARNT2 | c.2151G>A p.E717= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV57590802; called by muse, mutect2, varscan2
- GABRB3 | c.1405C>T p.L469= | Silent (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- ACVRL1 | c.1377+62C>T | Intron (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- TMEM70 | c.-61C>T | 5'UTR (SNP) | VAF 39/90 reads (43%) | catalogued as rs750271273; called by muse, mutect2, varscan2
